Surgical pathology report (de-identified scan), TCGA case TCGA-V5-AASV, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-AASV-01A (Primary Tumor).

Results

Surgical Pathology

Result Data

ACCESSION

ICD O-3
Carcinoma, squamous cell NOS
Site: Esophagus NOS
8070/3
C15.9

Entry Date

9/5 11/18/14

Component Results

Lab

Component

Clinical History

Esophageal cancer

Gross Examination

Outside case A:

Date of surgery:

Number of slides:

3

Received from:

Surgical Pathology Division

Outside path report received? Yes

Material to be returned? Yes

Microscopic Examination

Microscopic examination is performed.

Diagnosis

A. "ESOPHAGEAL MASS" (BIOPSY), OUTSIDE CASE,
DATE OF PROCEDURE

SQUAMOUS CELL CARCINOMA IN SITU AT LEAST, WITH FOCI SUSPICIOUS FOR
INVASIVE CARCINOMA.

COMMENT: Dr. has also reviewed this case and concurs.

Comment:

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

Electronically signed:

Testing Performed By

Lab - Abbreviation	Name	Director	Address	Valid Date Range
				Present

Lab and Collection

Surgical Pathology on

Result Information

Abnormality	Status	Priority	Source
	Final result	Routine	

Authorizing Provider Information

Name:

Fax:

Phone:

Pager:

Source: NCI Genomic Data Commons file c8098f4a-8d2a-4b8a-8ff9-afc266468984 (TCGA-V5-AASV.3E53EDF7-037C-4826-9825-32833B194566.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).